Somatic mutation profile of tumor specimen ALCH-B1VF-TTP1-A (aliquot ALCH-B1VF-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1VF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.8 years (24,778 days).
Specimen ALCH-B1VF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2275138f-33c9-4154-af9e-045454d1978e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1VF-NB1-A (Blood Derived Normal), aliquot ALCH-B1VF-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54de11d6-41e8-4f13-aade-49c5ec170d29

The open-access MAF lists 34 somatic variants for this specimen: 14 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 12, 3'UTR 5, RNA 1, Frame Shift Del 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/298 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- ANGPTL7 | c.273G>T p.M91I | Missense Mutation (SNP) | VAF 52/570 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV100815985; called by muse, mutect2
- CCT6A | c.1493A>G p.Y498C | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.304); catalogued as rs148027657; called by muse, mutect2
- DAB2 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 46/338 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs762576660, COSV104410411; called by muse, mutect2, varscan2
- MADD | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); catalogued as rs1013008661; called by muse, mutect2
- MED13L | c.5708G>A p.R1903H | Missense Mutation (SNP) | VAF 48/509 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1039753021, COSV56132224; called by muse, mutect2
- SETD2 | c.3932del p.G1311Vfs*21 | Frame Shift Del (DEL) | VAF 25/227 reads (11%) | catalogued as COSV57442438; called by mutect2, pindel, varscan2
- TMEM183A | c.860A>G p.N287S | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1422878248; called by muse, mutect2
- ZNF697 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 21/354 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV70284226; called by muse, mutect2
- ZNF84 | c.1460A>G p.Y487C | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV59654322; called by muse, mutect2, varscan2
- KDR | c.2242G>C p.V748L | Missense Mutation (SNP) | VAF 26/436 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2
- OR4Q3 | c.511C>A p.L171I | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- PARD3B | c.2218G>T p.G740C (on ENST00000406610 / NM_001302769.2; = p.G678C on NM_152526.6) | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRKAR2A | c.29T>A p.L10H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AEN | c.456C>A p.P152= | Silent (SNP) | VAF 40/557 reads (7%) | catalogued as COSV60430160; called by muse, mutect2
- CHRNA1 | c.171G>A p.L57= | Silent (SNP) | VAF 42/986 reads (4%) | catalogued as rs1314641395; called by muse, mutect2
- GAA | c.636G>A p.E212= | Silent (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- HS2ST1 | c.993C>T p.A331= | Silent (SNP) | VAF 24/286 reads (8%) | catalogued as rs746757317; called by muse, mutect2
- INTS6L | c.1635C>A p.S545= | Silent (SNP) | VAF 7/45 reads (16%) | called by muse, varscan2
- MED13 | c.5466C>T p.I1822= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs547385363, COSV67263333; called by muse, mutect2, varscan2
- NKIRAS2 | c.468C>G p.S156= | Silent (SNP) | VAF 37/545 reads (7%) | catalogued as rs1555653605; called by muse, mutect2
- OR7A17 | c.648C>T p.C216= | Silent (SNP) | VAF 18/256 reads (7%) | catalogued as rs1486813427; called by muse, mutect2
- PAQR9 | c.252G>A p.T84= | Silent (SNP) | VAF 18/356 reads (5%) | called by muse, mutect2
- PREX2 | c.912G>A p.V304= | Silent (SNP) | VAF 21/291 reads (7%) | catalogued as COSV55803679; called by muse, mutect2
- RBBP8NL | c.129C>G p.L43= | Silent (SNP) | VAF 20/276 reads (7%) | called by muse, mutect2
- XIRP2 | c.7134A>G p.Q2378= (on ENST00000628543; = p.Q2553= on NM_152381.6) | Silent (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- ARID5A | c.*74T>G | 3'UTR (SNP) | VAF 24/257 reads (9%) | called by muse, mutect2
- DAZL | c.*51G>C | 3'UTR (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- FGF2 | c.*32T>C | 3'UTR (SNP) | VAF 16/109 reads (15%) | called by muse, mutect2, varscan2
- FIBP | c.284+83A>T | Intron (SNP) | VAF 17/119 reads (14%) | catalogued as rs766595941; called by muse, mutect2, varscan2
- LAMP3 | c.*26A>G | 3'UTR (SNP) | VAF 22/206 reads (11%) | catalogued as rs769121427; called by muse, mutect2
- LINC01342 | n.321C>T | RNA (SNP) | VAF 12/70 reads (17%) | catalogued as rs1172891403; called by mutect2, varscan2
- MAU2 | c.*33C>G | 3'UTR (SNP) | VAF 25/593 reads (4%) | called by muse, mutect2
- MUC19 | chr12:40543814 T>C | 3'Flank (SNP) | VAF 7/54 reads (13%) | called by muse, varscan2
